FM case AD5693 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/9023cce4-c34d-42c9-bce3-fbea55801f87

Male, 71.5 years: Clear cell carcinoma (ICD-O-3 8310/3) of the kidney; metastasis biopsied or resected from the lung. Sample type: Metastatic.
